Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KB, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KB-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, adrenal Cortex
837013

Site: ① Adrenal Gland
Cortex C74.0
JW 1/28/13

DIAGNOSIS

- (A) LEFT ADRENAL MASS AND LEFT NEPHRECTOMY EN BLOC:
ADRENAL CORTICAL CARCINOMA. (SEE COMMENT)
TUMOR MEASURES 13.0 x 8.5 x 7.0 CM. (SEE COMMENT)
Margins of resection (peripheral soft tissue, vascular, and ureteral), no tumor present.
LYMPHOVASCULAR INVASION PRESENT.
Three hilar lymph nodes, no tumor present (0/3).
Renal parenchyma, no tumor present.

Entire report and diagnosis completed by

COMMENT

The periphery of the tumor is associated with marked fibrosis. The tumor invades into the adrenal capsule, but no unequivocal invasion into periadrenal soft tissue is identified.

Immunohistochemical stains show that the tumor is focally positive for keratin cocktail and inhibin and negative for calretinin, chromogranin, melan-A103, and S100. The overall morphologic and immunohistochemical features are consistent with the above diagnosis.

The tumor has areas of necrosis and prominent mitotic activity (129 mitotic figures/50 high-power fields), and the ki-67 index (performed by image analysis) is 79%.

Per the modified Weiss' criteria, the tumor has a score of 7 (Nuclear atypia: 1, Mitoses: 1, Atypical mitoses: 1, Spongiocytic tumor cells: 0, Diffuse architecture: 1, Venous invasion: 1, Sinus invasion: 0, Capsular invasion: 1, Necrosis: 1).

GROSS DESCRIPTION

(A) LEFT ADRENAL MASS AND LEFT NEPHRECTOMY EN BLOC - A radical nephrectomy specimen (18.0 x 12.0 x 8.0 cm), including the left kidney (12.0 x 5.2 x 4.9 cm), a segment of the renal artery, renal vein, and ureter (5.0 cm in length and 0.4 cm average diameter). There is a separate detached portion of perinephric adipose tissue (19.0 x 15.0 x 1.1 cm).

In the suprarenal location and contained within the fascia is a tumor (13.0 x 8.5 x 7.0 cm) that entirely replaces the adrenal gland. The tumor is variegated red-tan and bright yellow and friable. There are extensive areas of central hemorrhage (40-50%) and necrosis (30-40%). The tumor extends to less than 0.1 cm from the inked fascia. It is approximately 0.3 to 0.5 cm from the renal cortex. The tumor does not appear to invade into the renal parenchyma, or perinephric adipose tissue. The tumor does not invade into the renal sinus, renal vein, or pelvicalyceal system.

The majority of the kidney parenchyma is tan and unremarkable. The pelvicalyceal system is smooth and devoid of any lesions.

There are three possible lymph nodes (ranging from 1.3 cm to 1.5 cm, in greatest dimension) identified within the hilum of the kidney. Sectioning reveals a tan and yellow fatty surface.

Portions of the tumor and uninvolved parenchyma are submitted to the tissue bank.

INK CODE: Black - Gerota's fascia and outer surface of the perinephric fat near tumor.

SECTION CODE: A1, ureteral and vascular margins, en face; A2-A4, one possible lymph node bisected in each cassette; A5, mirror image of uninvolved renal parenchyma taken for tissue bank; A6, mirror image of tumor for tissue bank; A7-A8, uninvolved renal parenchyma; A9-A18, tumor, representative (A9, tumor with closest fascia, A10, tumor with necrosis, A11-A12,

[page 2 of 2]
[REDACTED]

tumor with perinephric fat, A13, tumor with renal parenchyma, A14, tumor with perinephric vessels, A15, tumor and perinephric fat, A16, A17, tumor with kidney, A18, tumor with possible residual adrenal gland), A19, tumor with fascia, A20, tumor with hemorrhage, A21, tumor with hemorrhage and kidney, A22, A23, perinephric fat, representative.

CLINICAL HISTORY

Left adrenal mass.

SNOMED CODES

T-71000, T-B3000, M-83703

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

[REDACTED]

These tests have not been

-----END OF REPORT-----

Diagnostic Discrepancy		
HP/AA Discrepancy		
HP/AA Malignancy History		

11/4/13

12/13

Source: NCI Genomic Data Commons file ae291952-8300-4fc2-8069-a7f762775a2e (TCGA-OR-A5KB.7553DC0B-FD8C-42E9-B38F-65EA954C6BC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).